Gene-level copy-number profile of tumor specimen C3N-05039-01 (profiled together with C3N-05039-02) from CPTAC case C3N-05039, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.0 years (27,030 days).
Specimen C3N-05039-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f8521c35-15f7-4c59-a660-fa21d368a7d4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-05039-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/8c0addc4-5dd6-4a19-a42c-8699e0d50204

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 13; copy number 2: 13,265; copy number 3: 2,597; copy number 4: 40,019; copy number 5: 10; copy number 6: 2,942.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:16,203,935–16,870,843, 6 genes: C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1.
- chr9:21,695,176–22,455,740, 18 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–2): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
